Somatic mutation profile of tumor specimen TCGA-24-1425-01A (aliquot TCGA-24-1425-01A-02W-0553-09) from TCGA case TCGA-24-1425, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 45.9 years (16,764 days).
Specimen TCGA-24-1425-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26c33eba-6419-4789-8390-42c974e2e175.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1425-10A (Blood Derived Normal), aliquot TCGA-24-1425-10A-01W-0553-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1cb7ad26-fe78-47e4-beb3-6ebd7cbaa650

The open-access MAF lists 86 somatic variants for this specimen: 59 protein-altering or splice-affecting, 26 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 26, Nonsense Mutation 4, Frame Shift Ins 2, RNA 1, Splice Region 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TBX6 | c.704dup p.M236Hfs*44 | Frame Shift Ins (INS) | VAF 14/78 reads (18%) | catalogued as rs758051786; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 45/111 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587780073, CM035576, COSV52661201, COSV52686167, COSV53142556; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABRA | c.878C>A p.T293N | Missense Mutation (SNP) | VAF 129/219 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV61733559; called by muse, mutect2, varscan2
- AFAP1L2 | c.1711G>A p.A571T | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV58418494; called by muse, varscan2
- ARFGEF2 | c.1434C>A p.F478L | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.951); catalogued as COSV100904409; called by muse, mutect2
- ARPP21 | c.1256C>T p.S419L | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV99492863; called by muse, mutect2, varscan2
- ASNS | c.158T>C p.V53A | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as COSV51556068; called by muse, mutect2, varscan2
- ATM | c.3011G>T p.S1004I | Missense Mutation (SNP) | VAF 51/329 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV53726192, COSV99591192; called by muse, mutect2, varscan2
- AUTS2 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.14); catalogued as COSV61429272; called by muse, mutect2, varscan2
- BCL2L1 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 72/436 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.112); catalogued as rs756076815, COSV100304805; called by muse, mutect2, varscan2
- CASD1 | c.1216A>G p.I406V | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.049); catalogued as rs755205087, COSV51975380; called by muse, mutect2, varscan2
- CSMD3 | c.3931A>C p.T1311P (on ENST00000297405 / NM_001363185.1; = p.T1207P on NM_052900.3) | Missense Mutation (SNP) | VAF 45/319 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV52313728, COSV99033773; called by muse, mutect2, varscan2
- DNASE1L3 | c.203G>T p.C68F | Missense Mutation (SNP) | VAF 10/205 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as COSV100568805; called by muse, mutect2
- DUSP16 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as COSV99963323; called by muse, mutect2, varscan2
- EFCAB6 | c.4016G>C p.R1339T | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV99414123; called by muse, mutect2
- ENPP2 | c.575T>A p.L192Q | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99309077; called by muse, mutect2, varscan2
- ERBIN | c.2937C>G p.I979M | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.499); catalogued as COSV52326764; called by muse, mutect2, varscan2
- FOXA3 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.041); catalogued as COSV100141476; called by muse, mutect2
- FOXP2 | c.1864C>G p.P622A | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100647189; called by muse, mutect2
- GRAMD2B | c.100G>A p.G34S | Missense Mutation (SNP) | VAF 34/499 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99587227; called by muse, mutect2
- GTF3A | c.1075G>A p.V359I | Missense Mutation (SNP) | VAF 123/317 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.079); catalogued as rs747831458, COSV63528777; called by muse, mutect2, varscan2
- HIVEP1 | c.4247C>A p.T1416N | Missense Mutation (SNP) | VAF 11/287 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as COSV101045554; called by muse, mutect2
- KCNMB2 | c.598C>G p.L200V | Missense Mutation (SNP) | VAF 61/195 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV64202048; called by muse, mutect2, varscan2
- MATR3 | c.2447C>G p.A816G | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1485650250, COSV100735289; called by muse, mutect2
- MED13 | c.5776A>C p.M1926L | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV101181259; called by muse, mutect2, varscan2
- NKTR | c.3608G>T p.S1203I | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV99236157; called by muse, mutect2
- NPHP1 | c.502G>C p.V168L | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV57211457; called by muse, mutect2, varscan2
- NT5DC1 | c.176G>A p.W59* | Nonsense Mutation (SNP) | VAF 15/135 reads (11%) | catalogued as COSV100127112; called by muse, mutect2, varscan2
- NUP210L | c.3148C>T p.L1050F | Missense Mutation (SNP) | VAF 52/167 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV55141359, COSV99668750; called by muse, mutect2, varscan2
- PCLO | c.1243G>T p.V415L | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs1008448932, COSV100436164; called by muse, mutect2, varscan2
- PLEKHG1 | c.284C>G p.S95* | Nonsense Mutation (SNP) | VAF 45/77 reads (58%) | catalogued as COSV62051016; called by muse, mutect2, varscan2
- PPP1R26 | c.584G>A p.G195D | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.258); catalogued as COSV100778133; called by muse, mutect2
- PRAMEF2 | c.548G>T p.S183I | Missense Mutation (SNP) | VAF 34/784 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.377); catalogued as COSV99535560; called by muse, mutect2
- PTPRB | c.494G>A p.W165* | Nonsense Mutation (SNP) | VAF 20/89 reads (22%) | catalogued as rs755159268, COSV99718558; called by muse, mutect2, varscan2
- PYHIN1 | c.437A>G p.E146G | Missense Mutation (SNP) | VAF 87/241 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV63723920; called by muse, mutect2, varscan2
- R3HDML | c.491C>A p.P164H | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as COSV99407248; called by muse, mutect2, varscan2
- RNF167 | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 53/601 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as COSV99337524; called by muse, mutect2
- RNF19A | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 59/390 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV61994730; called by muse, mutect2, varscan2
- ROBO3 | c.4028C>T p.T1343M | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.94); catalogued as rs745464981, COSV60627893; called by muse, mutect2
- SDHAF2 | c.350A>G p.D117G | Missense Mutation (SNP) | VAF 250/494 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.107); catalogued as rs151040226; called by muse, mutect2, varscan2
- SLC20A1 | c.1568C>T p.A523V | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99734186; called by muse, mutect2, varscan2
- SLC23A2 | c.1858C>G p.P620A | Missense Mutation (SNP) | VAF 59/229 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100595185; called by muse, mutect2, varscan2
- SLC35F1 | c.953C>G p.T318R | Missense Mutation (SNP) | VAF 86/323 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100838005; called by muse, mutect2, varscan2
- SORBS1 | c.1850C>A p.A617E | Missense Mutation (SNP) | VAF 20/467 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV99528702; called by muse, mutect2
- SORCS2 | c.2847C>A p.D949E | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as COSV100213453; called by muse, varscan2
- TACR3 | c.1387G>T p.E463* | Nonsense Mutation (SNP) | VAF 10/133 reads (8%) | catalogued as COSV100510797; called by muse, mutect2
- TCHHL1 | c.650A>T p.K217M | Missense Mutation (SNP) | VAF 117/301 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV64287552; called by muse, mutect2, varscan2
- TOP3B | c.1124T>C p.I375T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); catalogued as COSV100592703; called by muse, mutect2
- TRAK2 | c.854C>A p.S285Y | Missense Mutation (SNP) | VAF 12/292 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100217057; called by muse, mutect2
- TRIM37 | c.1210C>G p.R404G | Missense Mutation (SNP) | VAF 58/99 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51883161, COSV51888617; called by muse, mutect2, varscan2
- TUBA3C | c.1306G>T p.G436C | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV101313879; called by muse, mutect2, varscan2
- USH2A | c.11885A>G p.E3962G | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV56433363; called by muse, mutect2, varscan2
- ZBTB48 | c.1259C>G p.T420R | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV100887277; called by muse, mutect2
- ZCCHC7 | c.709G>C p.A237P | Missense Mutation (SNP) | VAF 77/283 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as COSV60962078; called by muse, mutect2, varscan2
- ZKSCAN4 | c.1346G>T p.R449I | Missense Mutation (SNP) | VAF 41/529 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV101043544; called by muse, mutect2
- ZNF646 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); catalogued as rs200713865, COSV100336821, COSV56213115; called by muse, mutect2, varscan2
- ZXDA | c.2399G>T p.*800Lext*11 | Nonstop Mutation (SNP) | VAF 6/92 reads (7%) | catalogued as COSV100699454; called by muse, mutect2
- CACNA1F | c.2421C>T p.D807= | Splice Region (SNP) | VAF 22/53 reads (42%) | called by muse, mutect2
- IFITM3 | c.54dup p.N19Qfs*3 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by pindel, varscan2
- AC004593.2 | c.525C>T p.N175= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as COSV56101433; called by muse, mutect2, varscan2
- AHNAK2 | c.8571G>A p.K2857= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV60927983, COSV60928861; called by muse, mutect2
- B3GAT2 | c.603C>A p.T201= | Silent (SNP) | VAF 13/144 reads (9%) | catalogued as COSV100017306; called by muse, mutect2
- CEP192 | c.3792G>T p.R1264= | Silent (SNP) | VAF 26/111 reads (23%) | catalogued as rs546519115, COSV58062309; called by muse, mutect2, varscan2
- CMYA5 | c.612T>A p.I204= | Silent (SNP) | VAF 21/358 reads (6%) | catalogued as COSV101484274; called by muse, mutect2
- COL6A3 | c.3702G>T p.V1234= | Silent (SNP) | VAF 20/124 reads (16%) | catalogued as COSV55108857; called by muse, mutect2, varscan2
- DCHS1 | c.1155T>G p.V385= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as COSV100202445; called by muse, mutect2
- DOCK8 | c.4119G>A p.G1373= | Silent (SNP) | VAF 7/110 reads (6%) | catalogued as COSV101210033; called by muse, mutect2
- DUSP16 | c.120C>T p.S40= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as COSV53808209; called by muse, mutect2, varscan2
- FLNB | c.3432G>A p.E1144= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV55894715; called by muse, mutect2, varscan2
- GATB | c.855C>A p.I285= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV99859236; called by muse, mutect2, varscan2
- GFAP | c.588G>A p.E196= | Silent (SNP) | VAF 132/351 reads (38%) | catalogued as COSV53653672; called by muse, mutect2, varscan2
- HCN3 | c.1428G>A p.L476= | Silent (SNP) | VAF 42/92 reads (46%) | catalogued as rs775047187, COSV100712988; called by muse, mutect2, varscan2
- HEXA | c.126C>T p.N42= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV99173814; called by muse, mutect2, varscan2
- IGLV4-69 | c.108C>T p.A36= | Silent (SNP) | VAF 5/133 reads (4%) | called by muse, mutect2
- LARGE1 | c.942G>A p.Q314= | Silent (SNP) | VAF 18/310 reads (6%) | catalogued as rs776701293, COSV100506134; called by muse, mutect2
- LRRC8E | c.930C>T p.S310= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100143087; called by muse, mutect2, varscan2
- MDGA1 | c.2733G>A p.L911= | Silent (SNP) | VAF 9/103 reads (9%) | catalogued as COSV99777231; called by muse, mutect2, varscan2
- NHLRC1 | c.936G>A p.L312= | Silent (SNP) | VAF 686/786 reads (87%) | catalogued as COSV100513529; called by muse, mutect2, varscan2
- PCDHA3 | c.1614C>T p.R538= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV63538652; called by muse, mutect2, varscan2
- SCN5A | c.102C>T p.R34= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs41313239; ClinVar: likely benign; called by muse, varscan2
- SLC9A5 | c.1884G>A p.A628= | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as rs369514722; called by muse, mutect2, varscan2
- SLCO5A1 | c.2172T>C p.G724= | Silent (SNP) | VAF 238/457 reads (52%) | catalogued as rs1437696279, COSV52667837; called by muse, mutect2, varscan2
- SUOX | c.454C>T p.L152= | Silent (SNP) | VAF 6/93 reads (6%) | catalogued as COSV99907182; called by muse, mutect2
- TUBA3C | c.1305G>T p.V435= | Silent (SNP) | VAF 34/212 reads (16%) | catalogued as COSV101313880; called by muse, mutect2, varscan2
- UNC79 | c.7704C>T p.I2568= (on ENST00000393151 / NM_001346218.2; = p.I2391= on NM_020818.5) | Silent (SNP) | VAF 56/270 reads (21%) | catalogued as rs1441227700, COSV99829387; called by muse, mutect2, varscan2
- MIR517C | n.36C>G | RNA (SNP) | VAF 124/525 reads (24%) | called by muse, mutect2, varscan2
